TCGA case TCGA-AB-2909 — Acute Myeloid Leukemia (TCGA-LAML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab60901b-d2ad-401a-9742-52df35ce1de0

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 22 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 22.5 years (8,220 days); Year of diagnosis: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 30 days; Calgb risk group: Intermediate/Normal; Fab morphology code: Not Classified.
   Recorded as not given: Pharmaceutical Therapy, NOS (Hydroxyurea), prior to procurement; Pharmaceutical Therapy, NOS (Tretinoin), prior to procurement.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 30.

Molecular and laboratory tests
- CBFB translocation (FISH): Abnormal, NOS; value 0 percent.
- CD117 (IHC): Positive.
- CD14 (IHC): Negative.
- CD33 (IHC): Negative.
- CD34 (IHC): Positive.
- CD5 (IHC): Negative.
- CD56 (IHC): Negative.
- FLT3 mutation, nos (RT-PCR): Positive.
- HLA-DR (IHC): Positive.
- IDH1 mutation, nos (RT-PCR): Negative; Amino-acid change: R132.
- IDH1 mutation, nos (RT-PCR): Negative; Amino-acid change: R140.
- IDH1 mutation, nos (RT-PCR): Negative; Amino-acid change: R172.
- KMT2A translocation (FISH): Abnormal, NOS; value 0 percent.
- MPO (IHC): Positive.
- NPM1 mutation, nos (RT-PCR): Negative.
- NSE (IHC): Positive.
- PML–RARA translocation (FISH): Abnormal, NOS; value 0 percent.
- RAS, NOS mutation, nos (RT-PCR): Negative.
- RUNX1–RUNX1T1 translocation (FISH): Abnormal, NOS; value 0 percent.
- Test (Cytogenetics, NOS): Normal.
- Test (FISH): Abnormal, NOS; value 0 percent.
- Bone Marrow neutrophil bands 0%.
- Bone Marrow metamyelocytes 0%.
- Bone Marrow abnormal cells 0%.
- Bone Marrow segmented neutrophil 2%.
- Bone Marrow blast count 94%.
- Metaphase Nucleus Count (Cytogenetics, NOS) 20.
- Bone Marrow lymphocytes 4%.
- Bone Marrow monocytes 0%.
- Bone Marrow promyelocytes 0%.
- Leukocytes 115 ×10³/µL.
- Blast Count 94%.
- Cellularity 90%.
- Bone Marrow eosinophil 0%.
- Bone Marrow myelocytes 0%.
- Hemoglobin 9 g/dL.
- Bone Marrow basophil 0%.
- Bone Marrow prolymphocytes 0%.
- Bone Marrow promonocytes 0%.
- Platelets 57 x10^6 cells/mcL.

Biospecimens (2 samples)
- Sample TCGA-AB-2909-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TCGA-AB-2909-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Cells used for analysis source: Bone marrow aspirate; History neoadjuvant treatment: No; Total dose: 0; History hematologic disorder: No; Hydroxyurea treatment days: 0; History neoadjuvant hydroxyurea treatment: No; Atra prior to procurement: No; Cytogenetics testing performed: Yes; Metaphases count: 20; Fish performed indicator: Yes; Fish abnormality detected: No; Molecular studies others performed: Yes; Molecular abnormality detected: Yes.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 1: Cyto and immuno test performed: MPX Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 2: Cyto and immuno test performed: NSE Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 3: Cyto and immuno test performed: TDT Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 4: Cyto and immuno test performed: CD3 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 5: Cyto and immuno test performed: CD5 Negative.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 6: Cyto and immuno test performed: CD7 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 7: Cyto and immuno test performed: CD10 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 8: Cyto and immuno test performed: CD14 Negative.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 9: Cyto and immuno test performed: CD15 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 10: Cyto and immuno test performed: CD19 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 11: Cyto and immuno test performed: CD20 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 12: Cyto and immuno test performed: CD23 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 13: Cyto and immuno test performed: CD25 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 14: Cyto and immuno test performed: CD33 Negative.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 15: Cyto and immuno test performed: CD34 Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 16: Cyto and immuno test performed: CD45 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 17: Cyto and immuno test performed: CD56 Negative.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 18: Cyto and immuno test performed: CD117 Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 19: Cyto and immuno test performed: HLA-DR Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 20: Cyto and immuno test performed: Other CD Not Tested.
- Fish test component results, Fish test component result 1: Test performed indicator: Pml-rar; Fish performed outcome: 0.
- Fish test component results, Fish test component result 2: Test performed indicator: MLL; Fish performed outcome: 0.
- Fish test component results, Fish test component result 3: Test performed indicator: CBF-Beta; Fish performed outcome: 0.
- Fish test component results, Fish test component result 4: Test performed indicator: AML1-ETO; Fish performed outcome: 0.
- Fish test component results, Fish test component result 5: Test performed indicator: +8; Fish performed outcome: 0.
- Fish test component results, Fish test component result 6: Test performed indicator: -7 or del(7q); Fish performed outcome: 0.
- Fish test component results, Fish test component result 7: Test performed indicator: -5 or del(5q); Fish performed outcome: 0.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 1: Molecular abnormality results: FLT3 Mutation Positive.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 2: Molecular abnormality results: IDH1 R132 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 3: Molecular abnormality results: IDH1 R140 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 4: Molecular abnormality results: IDH1 R172 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 5: Molecular abnormality results: Activating RAS Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 6: Molecular abnormality results: NPMc Negative.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 30 days; disease-specific survival: no event (censored), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AB-2909-03A-01D-0756-21): tumor purity 1, ploidy 1.99, whole-genome doublings 0.
